Somatic mutation profile of tumor specimen ALCH-AELD-TTP1-A (aliquot ALCH-AELD-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.9 years (25,900 days).
Specimen ALCH-AELD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189bb5e5-ec9b-49e0-9dc1-a16bf7d42b1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELD-NB1-A (Blood Derived Normal), aliquot ALCH-AELD-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b05cdc8-0f38-4748-a625-6f5c7c840605

The open-access MAF lists 276 somatic variants for this specimen: 184 protein-altering or splice-affecting, 55 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 55, Intron 24, Frame Shift Del 13, Nonsense Mutation 10, RNA 5, Splice Site 3, Frame Shift Ins 3, 3'UTR 3, 5'UTR 2, Splice Region 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 112/178 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1239985410, COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- PNPLA1 | c.614C>T p.P205L (on ENST00000394571 / NM_001374623.1; = p.P110L on NM_173676.2) | Missense Mutation (SNP) | VAF 69/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766215523; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 210/832 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1342620732, COSV63975109; called by muse, varscan2
- ADAMTS6 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 99/303 reads (33%) | catalogued as COSV66856688; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs781344386, COSV54461371; called by muse, mutect2, varscan2
- ADGRE5 | c.1297A>T p.S433C (on ENST00000242786 / NM_078481.4; = p.S340C on NM_001784.5) | Missense Mutation (SNP) | VAF 418/718 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs143754653; called by muse, mutect2, varscan2
- ATP2B3 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54855969; called by muse, mutect2, varscan2
- BRWD3 | c.1672C>A p.H558N | Missense Mutation (SNP) | VAF 56/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64753540; called by muse, mutect2, varscan2
- C7 | c.1290A>C p.E430D | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV57480877; called by muse, mutect2, varscan2
- CDC27 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1238314971, COSV50366964; called by muse, mutect2, varscan2
- CNTN1 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 110/433 reads (25%) | catalogued as rs1004715861; called by muse, mutect2, varscan2
- COL3A1 | c.2702A>G p.K901R | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs200717132, COSV58582268; called by muse, mutect2, varscan2
- COL4A3 | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 192/657 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as COSV67412604; called by muse, mutect2, varscan2
- COL9A1 | c.2528G>T p.R843L | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV57888307; called by muse, mutect2, varscan2
- CRACD | c.2116C>G p.R706G | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV51720188; called by muse, mutect2, varscan2
- CTAG2 | c.248C>A p.P83Q | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV55994830; called by muse, mutect2, varscan2
- DCAF11 | c.896del p.R299Pfs*12 | Frame Shift Del (DEL) | VAF 123/415 reads (30%) | catalogued as COSV100386633; called by mutect2, pindel, varscan2
- DGKZ | c.1989C>A p.F663L (on ENST00000454345 / NM_001105540.2; = p.F475L on NM_003646.4) | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100551162; called by muse, mutect2, varscan2
- DNAAF5 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.111); catalogued as rs1402359964; called by muse, mutect2, varscan2
- EIPR1 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs369361468; called by muse, mutect2, varscan2
- FBN1 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 52/663 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs869025407, CM972810, COSV57312455; ClinVar: uncertain significance; called by muse, mutect2
- GRM5 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 138/458 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59605441; called by muse, mutect2, varscan2
- HERC4 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 171/381 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53273878; called by muse, mutect2, varscan2
- HLF | c.773C>G p.S258W | Missense Mutation (SNP) | VAF 166/479 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56829665, COSV56832236; called by muse, mutect2, varscan2
- HNRNPUL1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746763454; called by muse, mutect2, varscan2
- HUWE1 | c.12880G>A p.A4294T | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1556909408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRAK3 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766993412; called by muse, mutect2, varscan2
- KANK4 | c.2071T>C p.S691P | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs201174577; called by muse, mutect2, varscan2
- KIAA0100 | c.2463C>A p.F821L | Missense Mutation (SNP) | VAF 134/598 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs763706049, COSV66493793; called by muse, mutect2, varscan2
- LARP4B | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs374286524; called by muse, mutect2, varscan2
- NEUROD4 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 107/364 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99669919; called by muse, mutect2, varscan2
- OR2F2 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV68833072; called by muse, mutect2, varscan2
- OR4Q3 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 146/423 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV59180143; called by mutect2, varscan2
- PDZRN4 | c.1763T>A p.L588Q (on ENST00000402685 / NM_001164595.2; = p.L330Q on NM_013377.4) | Missense Mutation (SNP) | VAF 149/503 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs754159088, COSV54219754; called by muse, mutect2, varscan2
- PKHD1L1 | c.3854T>C p.L1285P | Missense Mutation (SNP) | VAF 59/569 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV101006036; called by muse, mutect2, varscan2
- PLXNA3 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.586); catalogued as COSV100859917, COSV100860140; called by muse, mutect2
- PSME3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1389712225, COSV53198344, COSV53198935; called by muse, mutect2, varscan2
- PTCHD1 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.384); catalogued as rs759215971; called by muse, mutect2, varscan2
- RABL6 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs1008657189; called by muse, mutect2, varscan2
- RNF113A | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV65097642; called by muse, mutect2, varscan2
- RNF157 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1223784647, COSV53944017; called by muse, mutect2, varscan2
- SCRN2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs372666717; called by muse, mutect2, varscan2
- SOX13 | c.112del p.Q38Rfs*71 | Frame Shift Del (DEL) | VAF 69/318 reads (22%) | catalogued as COSV65827178; called by mutect2, pindel, varscan2
- TAF1L | c.5147C>A p.S1716Y | Missense Mutation (SNP) | VAF 131/462 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.272); catalogued as COSV54263842; called by muse, mutect2, varscan2
- TAF7L | c.719dup p.V241Gfs*3 | Frame Shift Ins (INS) | VAF 36/296 reads (12%) | catalogued as COSV61258097; called by mutect2, varscan2
- TBX5 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 343/860 reads (40%) | catalogued as rs1555226308; called by muse, mutect2, varscan2
- TG | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 213/604 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV104377518; called by muse, mutect2, varscan2
- TP53 | c.215_216del p.P72Rfs*76 | Frame Shift Del (DEL) | VAF 81/237 reads (34%) | catalogued as COSV52847066, COSV99452237; called by mutect2, pindel, varscan2
- UBE2S | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 121/429 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758572803, COSV99198782; called by muse, mutect2, varscan2
- VIM | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 193/697 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56405909; called by muse, mutect2, varscan2
- VPS13D | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as rs915499110, COSV50672484; called by muse, mutect2, varscan2
- WDR5 | c.36del p.A13Pfs*19 | Frame Shift Del (DEL) | VAF 41/301 reads (14%) | catalogued as COSV62272799; called by mutect2, pindel, varscan2
- WWC3 | c.1789del p.A597Pfs*28 | Frame Shift Del (DEL) | VAF 25/188 reads (13%) | catalogued as COSV66503822; called by mutect2, pindel, varscan2
- ZNF652 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1448777159, COSV62946810; called by muse, mutect2, varscan2
- ABCA4 | c.3130G>T p.A1044S | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ABCB4 | c.76A>T p.S26C | Missense Mutation (SNP) | VAF 267/944 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ABCC9 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 60/428 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ACTB | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 140/809 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTS20 | c.5237T>A p.M1746K | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ADCY8 | c.3371C>A p.T1124K | Missense Mutation (SNP) | VAF 210/552 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AL121899.2 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 128/499 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD36 | c.4492-1G>T p.X1498_splice | Splice Site (SNP) | VAF 24/52 reads (46%) | called by mutect2, varscan2
- ANO1 | c.1348G>C p.V450L | Missense Mutation (SNP) | VAF 142/547 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOE | c.237G>A p.R79= | Splice Region (SNP) | VAF 93/309 reads (30%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 44/353 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP11A | c.2718G>T p.M906I | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP18 | c.410T>C p.L137S | Missense Mutation (SNP) | VAF 128/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP35 | c.2646_2649del p.I883Sfs*3 | Frame Shift Del (DEL) | VAF 120/395 reads (30%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- ATP5F1B | c.30_44delinsA p.A11Gfs*61 | Frame Shift Del (DEL) | VAF 39/296 reads (13%) | called by pindel, varscan2*
- BTN2A3P | n.1448-5C>T | Splice Region (SNP) | VAF 74/529 reads (14%) | called by muse, mutect2, varscan2
- C4orf17 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 311/565 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CACNA1G | c.2693A>G p.D898G | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CATSPERG | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- CBLIF | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 136/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC59 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 125/493 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CDCP2 | c.492C>G p.N164K | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDH19 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK15 | c.638C>G p.A213G (on ENST00000652192 / NM_001366386.2; = p.A162G on NM_139158.2) | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CHD9 | c.2902A>T p.R968* | Nonsense Mutation (SNP) | VAF 122/334 reads (37%) | called by muse, varscan2
- CNTNAP2 | c.417C>G p.N139K | Missense Mutation (SNP) | VAF 157/670 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL14A1 | c.4385G>C p.G1462A | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DES | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLG3 | c.2362G>T p.D788Y (on ENST00000374360 / NM_021120.4; = p.D483Y on NM_020730.3) | Missense Mutation (SNP) | VAF 53/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- DUSP26 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- EN1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EPOP | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPX | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 204/662 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EYS | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBRSL1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGR2C | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL5 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 112/447 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FLG | c.10939G>A p.A3647T | Missense Mutation (SNP) | VAF 154/1316 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.91); called by muse, mutect2
- FLG | c.7051G>A p.A2351T | Missense Mutation (SNP) | VAF 91/991 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.168); called by muse, mutect2
- GAL | c.371_*22del | Nonstop Mutation (DEL) | VAF 86/376 reads (23%) | called by mutect2, pindel
- GCC1 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GK | c.618G>C p.M206I | Missense Mutation (SNP) | VAF 50/448 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRID2 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 134/247 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK2 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HECTD4 | c.8300A>T p.N2767I | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HHATL | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2
- HPGD | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 218/511 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INTS1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- IQSEC2 | c.2850G>C p.Q950H (on ENST00000642864 / NM_001111125.3; = p.Q745H on NM_015075.2) | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNA1 | c.1095G>T p.W365C | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIRREL2 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- KLHL13 | c.6T>A p.D2E | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- LILRB5 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAGEB6B | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MAGEC3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- MAGEE1 | c.2574G>T p.W858C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGEE2 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MAN2C1 | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP3K15 | c.3038C>G p.A1013G | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MAST4 | c.1953del p.G653Efs*6 (on ENST00000403625 / NM_001164664.2; = p.G464Efs*6 on NM_015183.3) | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | called by mutect2, pindel
- MATN4 | c.1522G>C p.V508L (on ENST00000372754; = p.V467L on NM_003833.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MINDY1 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MORF4L2 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MRM1 | c.781T>A p.S261T | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- N4BP1 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOA6 | c.4831A>G p.N1611D | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- NDUFS1 | c.1864del p.I622Lfs*2 | Frame Shift Del (DEL) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- NES | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NHLRC2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NHSL2 | c.535G>T p.A179S (on ENST00000510661; = p.A545S on NM_001013627.2) | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- NIN | c.5635C>T p.Q1879* (on ENST00000382041 / NM_182946.1; = p.Q1166* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 94/172 reads (55%) | called by muse, mutect2, varscan2
- NOX3 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPPC | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- OR2A2 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 107/355 reads (30%) | called by muse, mutect2, varscan2
- OR2T12 | c.765del p.F255Lfs*4 | Frame Shift Del (DEL) | VAF 221/779 reads (28%) | called by mutect2, pindel, varscan2
- OTUD6A | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX1 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PHACTR3 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 171/519 reads (33%) | called by muse, mutect2, varscan2
- PKDREJ | c.5378T>C p.L1793S | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PNMA3 | c.1363A>C p.K455Q | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTGIR | c.641_643del p.Y214_R215delinsC | In Frame Del (DEL) | VAF 56/228 reads (25%) | called by mutect2, pindel, varscan2
- RAB33A | c.589T>A p.C197S | Missense Mutation (SNP) | VAF 176/477 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABGGTA | c.900+1G>C p.X300_splice | Splice Site (SNP) | VAF 115/375 reads (31%) | called by muse, mutect2, varscan2
- RAG1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 130/506 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RARS2 | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 195/588 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RASAL1 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SBSN | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 211/756 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SCRIB | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINB3 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SIGLEC1 | c.4883T>A p.F1628Y | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC11 | c.1035A>C p.Q345H | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SKIDA1 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC17A5 | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC49A4 | c.291dup p.P98Afs*47 | Frame Shift Ins (INS) | VAF 146/466 reads (31%) | called by pindel, varscan2
- SLC9A7 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPAG1 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 141/392 reads (36%) | called by muse, mutect2, varscan2
- SREK1IP1 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- STPG2 | c.1100T>G p.V367G | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- TANC1 | c.5387A>G p.N1796S | Missense Mutation (SNP) | VAF 261/573 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS1R2 | c.2102G>A p.G701D | Missense Mutation (SNP) | VAF 275/840 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TBX18 | c.1209del p.N405Tfs*56 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by mutect2, pindel, varscan2
- TENM1 | c.4287G>T p.R1429S | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM127 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNN | c.3466G>C p.A1156P | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNR | c.2544T>A p.H848Q | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.214); called by muse, varscan2
- TRIM55 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 189/507 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRO | c.3149G>T p.G1050V | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TRPM8 | c.2355+2T>A p.X785_splice | Splice Site (SNP) | VAF 75/227 reads (33%) | called by muse, mutect2, varscan2
- TSC2 | c.3762_3763dup p.V1255Gfs*71 | Frame Shift Ins (INS) | VAF 117/344 reads (34%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.2864A>T p.Y955F | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TTN | c.19502T>A p.I6501N (on ENST00000591111; = p.I5574N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/280 reads (4%) | PolyPhen possibly damaging (0.888); called by muse, mutect2
- UROC1 | c.213C>G p.Y71* | Nonsense Mutation (SNP) | VAF 110/269 reads (41%) | called by muse, mutect2, varscan2
- UTP14C | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 209/444 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UTRN | c.6562G>T p.E2188* | Nonsense Mutation (SNP) | VAF 71/327 reads (22%) | called by muse, mutect2, varscan2
- VEPH1 | c.2105G>T p.C702F | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.8841del p.W2947Cfs*14 | Frame Shift Del (DEL) | VAF 177/511 reads (35%) | called by mutect2, pindel, varscan2
- WDR18 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H12D | c.104A>T p.D35V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZDHHC15 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZDHHC5 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZMYM2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF100 | c.1529A>T p.E510V | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ZNF212 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 69/552 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF41 | c.1899G>C p.K633N | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF521 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNF69 | c.1368del p.M456Ifs*14 | Frame Shift Del (DEL) | VAF 105/290 reads (36%) | called by mutect2, pindel, varscan2
- ABCA10 | c.558C>T p.C186= | Silent (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- ACTR3C | c.30C>G p.L10= | Silent (SNP) | VAF 108/393 reads (27%) | called by muse, mutect2, varscan2
- ALK | c.351G>T p.P117= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs1049747209; called by muse, mutect2, varscan2
- AP3B1 | c.2340C>T p.S780= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as rs199599147; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- API5 | c.360C>T p.A120= | Silent (SNP) | VAF 71/354 reads (20%) | called by muse, mutect2, varscan2
- ARMCX3 | c.367C>T p.L123= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- BRWD1 | c.6783G>A p.R2261= | Silent (SNP) | VAF 84/277 reads (30%) | catalogued as rs780691502; called by muse, mutect2, varscan2
- CBX2 | c.663C>T p.A221= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- CD300LB | c.378G>T p.A126= | Silent (SNP) | VAF 55/218 reads (25%) | catalogued as COSV100075589; called by muse, mutect2, varscan2
- CELSR2 | c.1002C>A p.G334= | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- COL12A1 | c.5412G>T p.R1804= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- CRACD | c.108C>A p.V36= | Silent (SNP) | VAF 67/230 reads (29%) | called by muse, mutect2, varscan2
- CYC1 | c.162C>G p.S54= | Silent (SNP) | VAF 86/304 reads (28%) | called by muse, mutect2, varscan2
- CYP11A1 | c.372G>A p.P124= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as rs772188130; called by muse, mutect2, varscan2
- DDX3X | c.1404C>A p.T468= (on ENST00000399959; = p.T469= on NM_001356.5) | Silent (SNP) | VAF 95/295 reads (32%) | called by muse, mutect2, varscan2
- DMD | c.5445T>C p.D1815= | Silent (SNP) | VAF 14/446 reads (3%) | called by muse, mutect2
- FCRL1 | c.969C>A p.A323= | Silent (SNP) | VAF 126/360 reads (35%) | called by muse, mutect2, varscan2
- FSIP2 | c.4182C>T p.S1394= | Silent (SNP) | VAF 65/243 reads (27%) | called by muse, mutect2, varscan2
- GSX1 | c.318C>A p.V106= | Silent (SNP) | VAF 57/102 reads (56%) | called by muse, mutect2, varscan2
- HEPH | c.3309G>A p.K1103= (on ENST00000343002; = p.K836= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 140/436 reads (32%) | catalogued as rs778951623, COSV100295550, COSV57959020; called by muse, mutect2, varscan2
- IGKV1-8 | c.318T>C p.Y106= | Silent (SNP) | VAF 133/294 reads (45%) | catalogued as rs757895004; called by muse, mutect2, varscan2
- KCTD14 | c.135C>T p.T45= | Silent (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- KIF21B | c.3930C>T p.P1310= (on ENST00000422435 / NM_001252100.2; = p.P1297= on NM_017596.4) | Silent (SNP) | VAF 125/420 reads (30%) | catalogued as rs761591988; called by muse, mutect2, varscan2
- MAGEB4 | c.681G>T p.L227= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as COSV100975102; called by muse, mutect2, varscan2
- MAGEC1 | c.1422C>A p.P474= | Silent (SNP) | VAF 64/445 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.3853T>C p.L1285= | Silent (SNP) | VAF 97/210 reads (46%) | called by muse, mutect2, varscan2
- MX2 | c.1077C>T p.L359= | Silent (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- NAT16 | c.927G>T p.V309= | Silent (SNP) | VAF 79/260 reads (30%) | called by muse, mutect2, varscan2
- NCCRP1 | c.693C>A p.S231= | Silent (SNP) | VAF 61/196 reads (31%) | called by muse, mutect2, varscan2
- NEURL4 | c.3189C>T p.G1063= | Silent (SNP) | VAF 87/186 reads (47%) | catalogued as COSV100222943; called by muse, mutect2, varscan2
- NPIPB15 | c.840T>C p.D280= | Silent (SNP) | VAF 156/876 reads (18%) | catalogued as rs1350232331; called by muse, mutect2, varscan2
- OBSCN | c.12843C>G p.A4281= | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as rs520479; called by muse, mutect2, varscan2
- OLAH | c.483C>T p.G161= (on ENST00000378228 / NM_001039702.3; = p.G214= on NM_018324.3) | Silent (SNP) | VAF 68/329 reads (21%) | called by muse, mutect2, varscan2
- OR6X1 | c.123G>T p.G41= | Silent (SNP) | VAF 50/164 reads (30%) | called by muse, mutect2, varscan2
- OR8K1 | c.246C>G p.V82= | Silent (SNP) | VAF 135/425 reads (32%) | called by muse, mutect2, varscan2
- PAPPA2 | c.852G>T p.R284= | Silent (SNP) | VAF 120/358 reads (34%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1638C>A p.G546= | Silent (SNP) | VAF 182/464 reads (39%) | catalogued as rs549562119; called by muse, mutect2, varscan2
- PCLO | c.15324A>G p.K5108= | Silent (SNP) | VAF 80/280 reads (29%) | catalogued as COSV61634616, COSV61654036; called by muse, mutect2, varscan2
- PDPR | c.525G>C p.V175= | Silent (SNP) | VAF 193/1085 reads (18%) | catalogued as rs1200205828; called by muse, mutect2, varscan2
- PPP1R27 | c.288G>A p.A96= | Silent (SNP) | VAF 86/283 reads (30%) | catalogued as rs374933397, COSV100367367; called by muse, mutect2, varscan2
- PRKAB2 | c.387G>T p.V129= | Silent (SNP) | VAF 93/311 reads (30%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.618C>T p.L206= | Silent (SNP) | VAF 82/205 reads (40%) | called by muse, mutect2, varscan2
- SCN10A | c.549G>C p.T183= | Silent (SNP) | VAF 94/223 reads (42%) | called by muse, mutect2, varscan2
- SCN1A | c.1275C>A p.A425= | Silent (SNP) | VAF 172/653 reads (26%) | catalogued as rs1057520401, COSV57662763; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHPRH | c.4431C>A p.I1477= (on ENST00000275233 / NM_001042683.3; = p.I1481= on NM_173082.3) | Silent (SNP) | VAF 90/281 reads (32%) | called by muse, mutect2, varscan2
- SNX7 | c.225A>G p.P75= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- TEK | c.582A>C p.I194= | Silent (SNP) | VAF 173/592 reads (29%) | called by muse, mutect2, varscan2
- TMEM108 | c.1350G>T p.V450= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- TMEM184B | c.1198C>T p.L400= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2
- TMEM26 | c.555G>T p.A185= | Silent (SNP) | VAF 133/319 reads (42%) | catalogued as COSV99515852; called by muse, mutect2, varscan2
- TRIM58 | c.954A>G p.P318= | Silent (SNP) | VAF 144/367 reads (39%) | called by muse, mutect2, varscan2
- TUBB8 | c.27C>A p.I9= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV59114795; called by muse, mutect2, varscan2
- VWA5B1 | c.72C>G p.V24= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- WNK3 | c.645T>C p.S215= | Silent (SNP) | VAF 41/256 reads (16%) | called by muse, mutect2, varscan2
- ZDBF2 | c.4839G>T p.L1613= | Silent (SNP) | VAF 87/376 reads (23%) | called by muse, mutect2, varscan2
- CCNC | c.347-22A>T | Intron (SNP) | VAF 27/79 reads (34%) | catalogued as rs758756123; called by muse, mutect2, varscan2
- CFAP54 | c.8281+29A>G | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- CYP2B7P | n.876+48A>G | Intron (SNP) | VAF 68/303 reads (22%) | called by muse, mutect2, varscan2
- DMAC2 | chr19:41440147 T>C | 5'Flank (SNP) | VAF 93/239 reads (39%) | called by muse, mutect2, varscan2
- DNAH14 | c.6033+2204C>A | Intron (SNP) | VAF 202/597 reads (34%) | called by muse, mutect2, varscan2
- DNMT1 | c.3262-30C>T | Intron (SNP) | VAF 170/587 reads (29%) | catalogued as rs764706999; called by muse, mutect2, varscan2
- EGLN1 | c.-27G>T | 5'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, varscan2
- EMC3-AS1 | chr3:10007530 G>T | 3'Flank (SNP) | VAF 110/286 reads (38%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7909C>T | Intron (SNP) | VAF 94/194 reads (48%) | called by muse, mutect2, varscan2
- FAM86DP | n.997C>T | RNA (SNP) | VAF 182/465 reads (39%) | catalogued as rs559044570; called by muse, mutect2, varscan2
- FER1L4 | n.2788G>T | RNA (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- GH2 | c.456+122C>T | Intron (SNP) | VAF 128/483 reads (27%) | catalogued as rs1187046149; called by muse, mutect2, varscan2
- GLYATL1 | c.-166-219C>T | Intron (SNP) | VAF 39/143 reads (27%) | catalogued as rs1172915525, COSV55609493; called by muse, mutect2, varscan2
- HNF1A | c.1309+44G>A | Intron (SNP) | VAF 122/309 reads (39%) | called by muse, varscan2
- KIF1B | c.2115+7000G>T | Intron (SNP) | VAF 64/322 reads (20%) | called by muse, mutect2, varscan2
- KLF6 | c.*1001T>A | 3'UTR (SNP) | VAF 63/201 reads (31%) | called by muse, mutect2, varscan2
- LAMA1 | c.8207+10A>T | Intron (SNP) | VAF 106/564 reads (19%) | catalogued as rs1395406905; called by muse, mutect2, varscan2
- LINC01547 | n.2738G>T | RNA (SNP) | VAF 55/201 reads (27%) | called by muse, mutect2, varscan2
- LY6E-DT | n.248G>A | RNA (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2
- MATR3 | c.*325C>G | 3'UTR (SNP) | VAF 42/191 reads (22%) | catalogued as rs1457202862; called by muse, mutect2, varscan2
- MCM4 | c.71-19C>G | Intron (SNP) | VAF 120/490 reads (24%) | called by muse, mutect2, varscan2
- MGAM | c.4619-2046G>T | Intron (SNP) | VAF 136/509 reads (27%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92848C>A | Intron (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2, varscan2
- MSC | c.534+121G>T | Intron (SNP) | VAF 47/239 reads (20%) | catalogued as COSV100335597; called by muse, mutect2, varscan2
- NR4A1 | c.160+1927G>T | Intron (SNP) | VAF 148/549 reads (27%) | called by muse, mutect2, varscan2
- RARS1 | c.46-376C>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- SEMA4C | c.110-125_110-107del | Intron (DEL) | VAF 40/272 reads (15%) | called by mutect2, pindel
- SEPTIN4 | c.1614+1467C>A | Intron (SNP) | VAF 24/110 reads (22%) | catalogued as rs1284005249; called by muse, mutect2, varscan2
- SPATA31C1 | n.523-23C>T | Intron (SNP) | VAF 255/750 reads (34%) | called by muse, mutect2, varscan2
- TCL1A | c.121-332C>T | Intron (SNP) | VAF 80/157 reads (51%) | catalogued as rs1328636433; called by muse, mutect2, varscan2
- TRIM51EP | n.761G>A | RNA (SNP) | VAF 82/493 reads (17%) | called by muse, mutect2, varscan2
- TSBP1 | c.257-261C>G | Intron (SNP) | VAF 63/416 reads (15%) | called by muse, mutect2, varscan2
- TTLL6 | c.324-20C>T | Intron (SNP) | VAF 82/298 reads (28%) | called by muse, mutect2, varscan2
- TTR | c.336+11A>C | Intron (SNP) | VAF 307/903 reads (34%) | catalogued as rs1238537578; called by muse, mutect2, varscan2
- VPS29 | c.-20G>C | 5'UTR (SNP) | VAF 96/309 reads (31%) | called by muse, mutect2, varscan2
- ZBTB24 | c.*146C>G | 3'UTR (SNP) | VAF 80/267 reads (30%) | called by muse, mutect2, varscan2
- ZNF559 | chr19:9324229 G>C | 5'Flank (SNP) | VAF 34/266 reads (13%) | called by muse, mutect2, varscan2
